Somatic mutation profile of tumor specimen TCGA-39-5016-01A (aliquot TCGA-39-5016-01A-01D-1441-08) from TCGA case TCGA-39-5016, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 44.6 years (16,306 days).
Specimen TCGA-39-5016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6243b4c7-d97c-4935-a488-e772edf18596.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5016-11A (Solid Tissue Normal), aliquot TCGA-39-5016-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17178b17-107a-4332-9741-8462400e210d

The open-access MAF lists 419 somatic variants for this specimen: 297 protein-altering or splice-affecting, 110 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 110, Nonsense Mutation 17, Frame Shift Del 13, Splice Site 7, Splice Region 5, Intron 5, RNA 4, 3'Flank 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 72/124 reads (58%) | catalogued as rs368007918, CM992836; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 35/72 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2452A>G p.T818A (on ENST00000272895 / NM_173076.3; = p.T500A on NM_015657.3) | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750076104, COSV55954124, COSV55961198; called by muse, mutect2, varscan2
- ABCC8 | c.3586del p.Q1196Sfs*12 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as CM147661; called by mutect2, pindel, varscan2
- ABCF2 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 50/313 reads (16%) | catalogued as COSV55181689; called by muse, mutect2, varscan2
- ABL1 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV59332852, COSV59336304; called by muse, mutect2, varscan2
- ACCSL | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66581383; called by muse, mutect2
- ACKR1 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs964838293, COSV63673027; called by muse, mutect2, varscan2
- ADAD2 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV51893660; called by muse, mutect2
- ADD2 | c.1150C>G p.R384G | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52456622, COSV52462275; called by muse, mutect2, varscan2
- ADGRF1 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV64800201; called by muse, mutect2, varscan2
- ANP32A | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV51189582; called by muse, mutect2, varscan2
- APOB | c.12261G>T p.K4087N | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760815617, COSV51937949; called by muse, mutect2, varscan2
- ARMC1 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV52533002; called by muse, mutect2, varscan2
- ASB5 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.339); catalogued as COSV56671217; called by muse, mutect2, varscan2
- ATF2 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV51369868; called by muse, mutect2, varscan2
- ATL2 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60052375; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2539T>A p.S847T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57749064, COSV57749661; called by muse, mutect2
- ATP6V0A2 | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100377155, COSV57749670; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as rs369999617; called by muse, mutect2, varscan2
- BAG6 | c.2776G>T p.G926W (on ENST00000676571; = p.G879W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52991290; called by muse, mutect2, varscan2
- BMPR1B | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as COSV52775424; called by muse, mutect2, varscan2
- BRI3BP | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58296288; called by muse, mutect2, varscan2
- BRINP2 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64177833; called by muse, mutect2, varscan2
- BUB1B | c.2534A>C p.Q845P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.756); catalogued as COSV55013163; called by muse, mutect2, varscan2
- C4orf19 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV52649442, COSV52649547; called by muse, mutect2, varscan2
- CACNA1I | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360035, COSV60801760, COSV60803716; called by muse, mutect2, varscan2
- CAPRIN2 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs753412572, COSV51832944; called by muse, mutect2, varscan2
- CASR | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV56137686; called by muse, mutect2, varscan2
- CATSPER1 | c.2126-1G>T p.X709_splice | Splice Site (SNP) | VAF 21/63 reads (33%) | catalogued as COSV56411055; called by muse, mutect2, varscan2
- CBX2 | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99490695; called by muse, mutect2, varscan2
- CCDC141 | c.3094G>A p.V1032I | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.23); catalogued as rs1238092224, COSV55374804; called by muse, mutect2, varscan2
- CCDC39 | c.2744C>A p.S915Y | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as COSV56011580; called by muse, mutect2, varscan2
- CCDC85A | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV68151401; called by muse, mutect2, varscan2
- CCHCR1 | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52535714; called by muse, mutect2, varscan2
- CDH10 | c.527-2A>G p.X176_splice | Splice Site (SNP) | VAF 34/102 reads (33%) | catalogued as COSV52582925; called by muse, mutect2, varscan2
- CDH18 | c.1211C>G p.T404R | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.178); catalogued as COSV56926578; called by muse, mutect2, varscan2
- CEACAM6 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 148/514 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV52267755; called by muse, mutect2, varscan2
- CFAP91 | c.331C>G p.H111D | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV56341432, COSV56345257; called by muse, mutect2, varscan2
- CHD8 | c.2680G>T p.A894S (on ENST00000646647 / NM_001170629.2; = p.A615S on NM_020920.4) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV67870778; called by muse, varscan2
- CHD8 | c.2606C>T p.S869F (on ENST00000646647 / NM_001170629.2; = p.S590F on NM_020920.4) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67870060; called by muse, varscan2
- CLEC18B | c.1312C>A p.R438S | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100375788; called by muse, mutect2, varscan2
- CLEC4C | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as rs768616751, COSV63582715; called by muse, mutect2, varscan2
- CNBD1 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV72917073; called by muse, mutect2
- CNTNAP1 | c.2985C>A p.C995* | Nonsense Mutation (SNP) | VAF 28/187 reads (15%) | catalogued as COSV52851025; called by muse, mutect2, varscan2
- COL19A1 | c.449A>C p.E150A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59574815; called by muse, mutect2, varscan2
- COL1A1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199510546, COSV56802573; called by muse, mutect2, varscan2
- COL22A1 | c.4639C>A p.P1547T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.652); catalogued as COSV57339392; called by muse, mutect2, varscan2
- COL22A1 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57339402; called by muse, mutect2, varscan2
- COL25A1 | c.1515G>A p.P505= | Splice Region (SNP) | VAF 29/136 reads (21%) | catalogued as rs371922822; called by muse, mutect2, varscan2
- COL4A3 | c.3590C>A p.P1197Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59258201; called by muse, mutect2, varscan2
- COL6A6 | c.3427C>A p.Q1143K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.76); catalogued as COSV62026782; called by muse, mutect2, varscan2
- COL6A6 | c.3428A>G p.Q1143R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.867); catalogued as COSV62026798; called by muse, mutect2, varscan2
- COX7B2 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs750184358, COSV100260306; called by muse, mutect2, varscan2
- CPS1 | c.189T>G p.H63Q | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.29); catalogued as COSV51812002; called by muse, mutect2, varscan2
- CRISP2 | c.504A>T p.Q168H | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV59255001; called by muse, mutect2, varscan2
- CSMD1 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.364); catalogued as COSV68210767; called by muse, mutect2, varscan2
- CSPP1 | c.2061G>T p.R687S (on ENST00000676605; = p.R646S on NM_024790.6) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51585342; called by muse, mutect2, varscan2
- CST4 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1274607104, COSV54149770; called by muse, mutect2, varscan2
- CTSD | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs377696355; called by muse, mutect2, varscan2
- CUL3 | c.2029G>T p.V677F | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV52365373; called by muse, mutect2
- CXCL5 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56018651; called by muse, mutect2, varscan2
- CYP3A43 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 10/164 reads (6%) | catalogued as rs1454688299, COSV55936397; called by muse, mutect2
- CYRIA | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV62865357; called by muse, mutect2, varscan2
- DENND1C | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV67373576; called by muse, mutect2, varscan2
- DGKI | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV55953015; called by muse, mutect2
- DGKK | c.645G>A p.K215= | Splice Region (SNP) | VAF 22/39 reads (56%) | catalogued as COSV65707737; called by muse, mutect2, varscan2
- DMKN | c.918+2T>A p.X306_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV60086741; called by muse, mutect2, varscan2
- DNAH10 | c.9903T>A p.F3301L (on ENST00000409039; = p.F3240L on NM_207437.3) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68994887; called by muse, mutect2, varscan2
- DNAH7 | c.6728A>T p.E2243V | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56767589; called by muse, mutect2, varscan2
- DNAH9 | c.5882G>T p.S1961I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV52352761; called by muse, mutect2, varscan2
- DOCK4 | c.1382A>G p.H461R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101455469; called by muse, mutect2
- EMC7 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1280712415, COSV56627987; called by muse, mutect2, varscan2
- EML1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV51746129; called by muse, mutect2, varscan2
- ERBB4 | c.3707C>A p.A1236E | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV61458996, COSV61492291; called by muse, mutect2, varscan2
- EVPL | c.4631A>G p.N1544S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56911943; called by muse, mutect2, varscan2
- FAM110B | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100826058, COSV64065192; called by muse, mutect2, varscan2
- FAM135B | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52728907; called by muse, mutect2, varscan2
- FAM155A | c.791G>C p.C264S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV65564744; called by muse, mutect2, varscan2
- FAM83H | c.2012G>T p.R671L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62028616; called by mutect2, varscan2
- FASTKD1 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 142/352 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52930426; called by muse, mutect2, varscan2
- FAT4 | c.8695A>G p.T2899A | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1222443293, COSV58688515; called by muse, mutect2, varscan2
- FBLN5 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV50904258, COSV99969596; called by muse, mutect2, varscan2
- FBXL7 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs1187472492, COSV100309107, COSV61646956; called by muse, mutect2, varscan2
- FBXW9 | c.472C>G p.L158V (on ENST00000587955; = p.L168V on NM_032301.3) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV63508579; called by muse, mutect2, varscan2
- FCHO1 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53182930; called by muse, mutect2, varscan2
- FIGN | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60767352; called by muse, mutect2, varscan2
- FLRT2 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58142651; called by muse, varscan2
- FLRT2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58142665; called by muse, mutect2, varscan2
- FNDC1 | c.2020C>G p.R674G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51939223, COSV51945533; called by muse, mutect2, varscan2
- FOXK2 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58879484; called by muse, mutect2, varscan2
- FRK | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 40/182 reads (22%) | catalogued as rs769521421, COSV73384004; called by muse, mutect2, varscan2
- FRMPD3 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.234); catalogued as COSV99345854; called by muse, mutect2, varscan2
- FRY | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 229/414 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV66569879; called by muse, mutect2, varscan2
- FRYL | c.1952C>A p.A651E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV51949103; called by muse, mutect2, varscan2
- FSIP2 | c.18715C>A p.P6239T | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV100554405, COSV58091951; called by muse, mutect2, varscan2
- GABRB3 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54661471, COSV54667048; called by muse, mutect2, varscan2
- GALNS | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM105256, COSV51937882; called by muse, mutect2, varscan2
- GDA | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV52993755; called by muse, mutect2, varscan2
- GGTLC1 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV53848295; called by muse, mutect2, varscan2
- GOLGA5 | c.2033G>T p.S678I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV50833311; called by muse, mutect2, varscan2
- GPC5 | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV65602103; called by muse, mutect2, varscan2
- GPR141 | c.17C>A p.T6N | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs199643208, COSV57732535; called by muse, mutect2, varscan2
- GPR162 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs367859986, COSV104376055; called by mutect2, varscan2
- GPR6 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51572036; called by muse, mutect2
- GRM5 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59607537; called by muse, mutect2, varscan2
- GTPBP4 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs756688779, COSV52988180; called by muse, varscan2
- HBD | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as COSV53082793; called by muse, mutect2, varscan2
- HBE1 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV53080203, COSV53081690; called by muse, mutect2, varscan2
- HELZ2 | c.3986G>T p.R1329L (on ENST00000467148 / NM_001037335.2; = p.R760L on NM_033405.3) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV101427532; called by muse, mutect2, varscan2
- HEPACAM2 | c.1012G>A p.G338R (on ENST00000394468 / NM_001039372.4; = p.G326R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59060779; called by muse, mutect2, varscan2
- HEPHL1 | c.1258G>T p.G420W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100243647; called by muse, mutect2, varscan2
- HIVEP1 | c.3146G>T p.G1049V | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV65102112; called by muse, mutect2, varscan2
- HLA-G | c.678G>T p.R226S | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64405935; called by muse, mutect2, varscan2
- HMCN1 | c.7550G>T p.G2517V | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54904954; called by muse, mutect2, varscan2
- HSD17B12 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV53500104; called by muse, mutect2, varscan2
- HYDIN | c.2074A>T p.R692W | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55487066; called by muse, mutect2, varscan2
- IFTAP | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57557899; called by muse, mutect2, varscan2
- IGFBP6 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56857435; called by muse, mutect2, varscan2
- IGKV5-2 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1160244425; called by muse, varscan2
- IGSF9 | c.3458G>A p.R1153H (on ENST00000368094 / NM_001135050.2; = p.R1137H on NM_020789.4) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs1038121889, COSV57422419; called by muse, mutect2, varscan2
- IGSF9B | c.2984T>A p.V995D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV58068346; called by muse, mutect2, varscan2
- IGSF9B | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); catalogued as COSV58068362; called by muse, mutect2, varscan2
- IRAK1 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.356); catalogued as COSV64111238; called by muse, mutect2, varscan2
- IRX1 | c.209A>T p.Y70F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV57360862; called by muse, varscan2
- KALRN | c.5578C>A p.L1860I (on ENST00000360013 / NM_001024660.4; = p.L163I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV52257605, COSV52259942; called by muse, mutect2, varscan2
- KCNH7 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59798759; called by muse, mutect2, varscan2
- KCNMA1 | c.985del p.E329Kfs*60 | Frame Shift Del (DEL) | VAF 52/314 reads (17%) | catalogued as COSV99700433; called by mutect2, pindel, varscan2
- KIAA1549 | c.4228A>C p.R1410= | Splice Region (SNP) | VAF 20/107 reads (19%) | catalogued as COSV54316061; called by muse, mutect2, varscan2
- KLF10 | c.343T>G p.S115A | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV53435661; called by muse, mutect2, varscan2
- KLHL26 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56317577, COSV56318008; called by muse, mutect2, varscan2
- KNOP1 | c.962A>T p.N321I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54928455; called by muse, mutect2
- KRTAP10-5 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1569198984, COSV59964823, COSV59969245; called by muse, mutect2
- L3MBTL1 | c.1309G>A p.V437M (on ENST00000418998 / NM_001377303.1; = p.V347M on NM_015478.7) | Missense Mutation (SNP) | VAF 147/389 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1484374546, COSV64228696; called by muse, mutect2, varscan2
- LARGE1 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 109/196 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100506776, COSV61662829; called by muse, mutect2, varscan2
- LAS1L | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV56707573; called by muse, mutect2, varscan2
- LEPR | c.2578T>A p.L860I | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as rs751425285, COSV60756389; called by muse, mutect2, varscan2
- MAGEB6 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 163/234 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV66871992, COSV66872365, COSV66872594; called by muse, mutect2, varscan2
- MAGEE1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV63910540; called by muse, mutect2, varscan2
- MAN2A1 | c.2821G>T p.G941W | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54852488; called by muse, mutect2, varscan2
- MARF1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1368928774, COSV60024275; called by muse, mutect2, varscan2
- MECOM | c.2145G>T p.R715S (on ENST00000468789 / NM_001105078.4; = p.R903S on NM_004991.4) | Missense Mutation (SNP) | VAF 132/210 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV52965463; called by muse, mutect2, varscan2
- MED28 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52846393; called by muse, mutect2, varscan2
- METTL8 | c.606+1G>C p.X202_splice | Splice Site (SNP) | VAF 51/277 reads (18%) | catalogued as COSV64550017; called by muse, mutect2, varscan2
- MGA | c.4193C>T p.S1398F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765943726, COSV54955256, COSV54955756; called by muse, mutect2, varscan2
- MITD1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99175546; called by muse, mutect2, varscan2
- MLLT3 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63497893; called by muse, mutect2, varscan2
- MMP15 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV54679069, COSV54679974; called by muse, mutect2, varscan2
- MOV10L1 | c.1754A>T p.K585I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV53172785; called by muse, mutect2, varscan2
- MTMR8 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV66394170; called by muse, mutect2, varscan2
- MUC5B | c.14882A>T p.K4961M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV71592363; called by muse, mutect2, varscan2
- MYH7 | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62519883; called by muse, mutect2
- MYLPF | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV58442450; called by muse, mutect2, varscan2
- MYO6 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV64119326; called by mutect2, varscan2
- NAXD | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as COSV57286429, COSV57290662; called by muse, mutect2, varscan2
- NDN | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); catalogued as COSV59360001; called by muse, mutect2, varscan2
- NEO1 | c.2819C>T p.T940I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773755176, COSV56071995; called by muse, mutect2, varscan2
- NFATC1 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV99500942; called by muse, mutect2, varscan2
- NFIL3 | c.32A>T p.K11M | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52683800; called by muse, mutect2, varscan2
- NKX3-2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV66711697; called by muse, mutect2
- NLRP14 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866354589, COSV55067734; called by muse, mutect2, varscan2
- NLRP5 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as rs1227604088, COSV66765112; called by muse, mutect2, varscan2
- NOB1 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1281112665, COSV52061880; called by muse, mutect2, varscan2
- NOL4 | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV52348778; called by muse, mutect2, varscan2
- NRAP | c.2142C>G p.S714R (on ENST00000359988 / NM_001322945.2; = p.S679R on NM_006175.4) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63491039; called by muse, mutect2, varscan2
- NTSR2 | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV60991313; called by muse, mutect2, varscan2
- NTSR2 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60991322; called by muse, mutect2, varscan2
- NUDT1 | c.533C>T p.T178M (on ENST00000397048 / NM_198952.1; = p.T155M on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs746490760, COSV56127286; called by muse, mutect2
- NXPE4 | c.1127C>T p.S376F (on ENST00000375478 / NM_001077639.2; = p.S92F on NM_017678.3) | Missense Mutation (SNP) | VAF 79/327 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV64943827; called by muse, mutect2, varscan2
- OR10G9 | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV66686291, COSV66686360; called by muse, mutect2, varscan2
- OR2A5 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as COSV68738799; called by muse, mutect2, varscan2
- OR4A16 | c.455T>A p.V152E | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV59043396, COSV59044964; called by muse, mutect2, varscan2
- OR4C12 | c.615C>A p.C205* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as COSV58860162, COSV58861281; called by muse, mutect2, varscan2
- OR4C6 | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV58604325; called by muse, mutect2, varscan2
- OR51A7 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV63788453; called by muse, mutect2, varscan2
- OR52J3 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1291796968, COSV66747043, COSV66747539; called by muse, mutect2, varscan2
- OR52R1 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198700061, COSV61888539, COSV61889336; called by muse, mutect2
- OR5B2 | c.916del p.Q306Kfs*? | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as rs749598407; called by mutect2, pindel, varscan2
- OR5D14 | c.810del p.Q271Kfs*17 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as COSV59458384; called by mutect2, pindel, varscan2
- OR5F1 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546780; called by muse, mutect2, varscan2
- PACS2 | c.2627A>C p.H876P | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57653393; called by muse, mutect2, varscan2
- PAQR8 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV62442744; called by muse, varscan2
- PCDH15 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1376087291, COSV57312785; called by muse, mutect2, varscan2
- PCDHA1 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65374709; called by muse, mutect2, varscan2
- PCDHGA12 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV52754069; called by muse, mutect2, varscan2
- PCDHGA5 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 160/304 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53960525, COSV53988506; called by muse, mutect2, varscan2
- PDIA2 | c.1043C>A p.A348E | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV51986214, COSV51988242; called by muse, mutect2
- PDZRN4 | c.1373G>T p.G458V (on ENST00000402685 / NM_001164595.2; = p.G200V on NM_013377.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54198138, COSV54213978; called by muse, mutect2, varscan2
- PER1 | c.3584G>T p.R1195L | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV57919813; called by muse, varscan2
- PHF21A | c.279G>T p.Q93H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57654684; called by muse, mutect2, varscan2
- PI16 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1394830263, COSV65448063; called by muse, mutect2, varscan2
- PIK3AP1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.229); catalogued as COSV59533186; called by muse, mutect2, varscan2
- PKHD1 | c.1817G>C p.R606P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV100584179, COSV61878512, COSV99049395; called by muse, mutect2, varscan2
- PLA2G4A | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs370896190, COSV66552649; called by muse, mutect2, varscan2
- PLEKHA7 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60580575; called by muse, mutect2
- PLRG1 | c.1486-1G>C p.X496_splice | Splice Site (SNP) | VAF 43/101 reads (43%) | catalogued as COSV100123013; called by muse, mutect2, varscan2
- PLVAP | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.277); catalogued as COSV53085534; called by muse, mutect2, varscan2
- POM121L12 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68693109; called by muse, mutect2, varscan2
- PPP1R16B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs774196620, COSV55378047; called by muse, mutect2, varscan2
- PPRC1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); catalogued as COSV53385779, COSV53385800; called by muse, mutect2, varscan2
- PRDM12 | c.410G>A p.W137* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV53390627; called by muse, mutect2, varscan2
- PRDM9 | c.1840G>T p.G614W | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57006742, COSV99689965; called by muse, varscan2
- PRKACG | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145926335; called by muse, mutect2, varscan2
- PRKAG3 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV52102130; called by muse, mutect2, varscan2
- PRKG1 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100907260, COSV64771298; called by muse, mutect2, varscan2
- PSME4 | c.2637A>G p.I879M | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV66365412; called by muse, mutect2, varscan2
- RAD50 | c.3211C>T p.H1071Y | Missense Mutation (SNP) | VAF 147/259 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54752293; called by muse, mutect2, varscan2
- RBMXL1 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 143/282 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53101777; called by muse, varscan2
- RC3H1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs372479139, COSV51202034; called by muse, mutect2, varscan2
- RDH8 | c.533C>T p.S178F (on ENST00000651512; = p.S158F on NM_015725.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50675314; called by muse, mutect2, varscan2
- RNF186 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 59/105 reads (56%) | catalogued as COSV64296790; called by muse, mutect2, varscan2
- ROBO4 | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1386733648, COSV60624557; called by muse, varscan2
- ROBO4 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV60624568; called by muse, mutect2, varscan2
- RP1 | c.6059A>C p.N2020T | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.273); catalogued as COSV55118149; called by muse, mutect2, varscan2
- RXRG | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 49/133 reads (37%) | catalogued as COSV63232249; called by muse, mutect2, varscan2
- SARAF | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV56357488; called by muse, mutect2, varscan2
- SATB2 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV53484932; called by muse, mutect2
- SCTR | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV50028432; called by muse, mutect2, varscan2
- SEMA3B | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60351731; called by muse, mutect2, varscan2
- SEMA3E | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV57091012, COSV57092683; called by muse, varscan2
- SERPINB2 | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55092804; called by muse, mutect2, varscan2
- SETD5 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs772295729, COSV56711665; called by muse, mutect2, varscan2
- SIGLEC15 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV67181176; called by muse, mutect2, varscan2
- SIKE1 | c.159+5G>T | Splice Region (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99285197; called by muse, mutect2, varscan2
- SLC16A14 | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618950; called by muse, mutect2, varscan2
- SLC22A1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100266536, COSV61454108; called by muse, mutect2
- SLC22A10 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60421535; called by muse, mutect2, varscan2
- SLC30A7 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV63017713; called by muse, mutect2, varscan2
- SLC6A18 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.255); catalogued as COSV57251663; called by muse, varscan2
- SLC7A2 | c.1234G>T p.D412Y (on ENST00000494857 / NM_001370338.1; = p.D451Y on NM_003046.6) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50255259; called by muse, mutect2, varscan2
- SLCO1B1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57011893; called by muse, mutect2, varscan2
- SMG8 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV56285626; called by muse, mutect2, varscan2
- SNX5 | c.755A>G p.H252R | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs767828190, COSV66698013; called by muse, mutect2, varscan2
- SOGA3 | c.2034C>A p.N678K | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV64106847; called by muse, mutect2, varscan2
- SPANXN2 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 272/486 reads (56%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as rs782025975, COSV65127639; called by muse, varscan2
- SPATA31A3 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1439407192; called by mutect2, varscan2
- SPHKAP | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60881339; called by muse, mutect2, varscan2
- SPTA1 | c.523G>T p.G175* | Nonsense Mutation (SNP) | VAF 409/616 reads (66%) | catalogued as COSV63754230; called by muse, mutect2, varscan2
- SPTB | c.5719C>G p.R1907G | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67632342; called by muse, mutect2, varscan2
- SRCAP | c.1137A>T p.I379= | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as COSV52673590; called by muse, mutect2
- STC2 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 283/544 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54180156; called by muse, mutect2, varscan2
- SV2B | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV57700110; called by muse, mutect2, varscan2
- SYT13 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV50072475; called by muse, mutect2, varscan2
- TAS2R60 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.629); catalogued as COSV60331071; called by muse, mutect2, varscan2
- TDRD6 | c.2264G>T p.C755F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60176188; called by muse, mutect2, varscan2
- TIMM21 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV50053789; called by muse, mutect2
- TLE5 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55592225; called by muse, mutect2, varscan2
- TMEM108 | c.1315T>C p.W439R | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58872930; called by muse, mutect2, varscan2
- TMF1 | c.634A>T p.N212Y | Missense Mutation (SNP) | VAF 119/231 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV68374467; called by muse, mutect2, varscan2
- TNS1 | c.4414C>A p.Q1472K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50706889; called by muse, mutect2, varscan2
- TONSL | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV68048417; called by muse, mutect2, varscan2
- TRAPPC8 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs773906123, COSV51971823; called by muse, varscan2
- TRO | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV51502334; called by muse, mutect2, varscan2
- TSC1 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.715); catalogued as rs796053461, COSV53767202; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTF1 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as rs773873964, COSV57502583, COSV57504544; called by muse, mutect2
- TTN | c.61237G>A p.D20413N (on ENST00000591111; = p.D12989N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/120 reads (18%) | PolyPhen benign (0.043); catalogued as COSV60104159; called by muse, mutect2, varscan2
- TTN | c.45664G>A p.D15222N (on ENST00000591111; = p.D7798N on NM_003319.4) | Missense Mutation (SNP) | VAF 28/197 reads (14%) | PolyPhen possibly damaging (0.6); catalogued as rs1427198480, COSV60104204; called by muse, mutect2, varscan2
- TTN | c.45013C>T p.R15005W (on ENST00000591111; = p.R7581W on NM_003319.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen possibly damaging (0.788); catalogued as rs794729448, COSV60104228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.36358C>T p.R12120C (on ENST00000591111; = p.R4696C on NM_003319.4) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | PolyPhen possibly damaging (0.721); catalogued as rs376166350; called by muse, mutect2, varscan2
- TYRO3 | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV55483678; called by muse, mutect2, varscan2
- UGT2B4 | c.1558A>G p.R520G | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV59315831; called by muse, mutect2
- UGT2B4 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59317704; called by muse, mutect2
- UPP2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | catalogued as COSV50046696, COSV50047296; called by muse, mutect2, varscan2
- USH2A | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 124/187 reads (66%) | catalogued as COSV56378175; called by muse, mutect2, varscan2
- VPS13B | c.8115G>T p.R2705S | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV62144189; called by muse, mutect2, varscan2
- VWCE | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57112822; called by muse, mutect2, varscan2
- WARS2 | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52478909; called by muse, mutect2, varscan2
- WASL | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as rs755860707, COSV56134013; called by muse, mutect2, varscan2
- WNT6 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs140404341, COSV52110193; called by muse, mutect2, varscan2
- ZAN | c.7127G>A p.R2376H | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs757015084, COSV61810007; called by muse, mutect2, varscan2
- ZBTB18 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV62397114; called by muse, mutect2, varscan2
- ZDBF2 | c.3976G>A p.D1326N | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV65626692; called by muse, mutect2, varscan2
- ZDHHC6 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65564533; called by muse, mutect2, varscan2
- ZEB2 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs748955225, COSV57957785; called by muse, mutect2, varscan2
- ZFHX4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV50897029; called by muse, mutect2, varscan2
- ZNF229 | c.1648G>C p.G550R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV52162332; called by muse, mutect2, varscan2
- ZNF292 | c.5806G>C p.E1936Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV60536196, COSV60539223, COSV60540195; called by muse, mutect2, varscan2
- ZNF540 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.075); catalogued as COSV57109573; called by muse, mutect2, varscan2
- ZNF540 | c.1542G>C p.Q514H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.589); catalogued as rs767033737, COSV57109587; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58673656; called by muse, mutect2, varscan2
- ARHGAP22 | c.709del p.E237Sfs*37 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- COL11A1 | c.1992del p.Q665Sfs*7 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- DNAH8 | c.6384del p.S2130Vfs*12 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- GOLGA3 | c.681del p.L228Ffs*46 | Frame Shift Del (DEL) | VAF 150/420 reads (36%) | called by mutect2, pindel, varscan2
- IGKC | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- IGKV1D-16 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 45/303 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- KIR3DL1 | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LATS1 | c.2641dup p.D881Gfs*40 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- NBPF15 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 192/315 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NYAP2 | c.219_221+5del p.X73_splice | Splice Site (DEL) | VAF 13/28 reads (46%) | called by mutect2, varscan2
- SFI1 | c.246del p.L83* | Frame Shift Del (DEL) | VAF 69/290 reads (24%) | called by mutect2, pindel, varscan2
- SRBD1 | c.1753_1754del p.L585Afs*25 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- SYNE1 | c.23831del p.A7944Dfs*49 (on ENST00000367255 / NM_182961.4; = p.A7873Dfs*49 on NM_033071.3) | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- TPTE | c.1067C>A p.S356Y (on ENST00000618007 / NM_199261.4; = p.S338Y on NM_199259.4) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- TRBV2 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.13del p.A5Hfs*33 | Frame Shift Del (DEL) | VAF 52/124 reads (42%) | called by mutect2, pindel, varscan2
- ZBTB46 | c.1307_1338del p.H436Pfs*93 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel
- ABCG4 | c.624T>C p.R208= | Silent (SNP) | VAF 52/201 reads (26%) | catalogued as COSV56643821; called by muse, mutect2, varscan2
- ABHD12 | c.978C>A p.L326= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV59285274, COSV59286032, COSV59286250; called by muse, mutect2, varscan2
- ACTA1 | c.819G>T p.S273= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV64203479; called by muse, mutect2, varscan2
- ADGRF5 | c.2355C>G p.T785= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV51934700; called by muse, mutect2, varscan2
- AHNAK2 | c.11265G>T p.A3755= | Silent (SNP) | VAF 65/277 reads (23%) | catalogued as rs368041963, COSV60917163; called by muse, mutect2, varscan2
- ANKK1 | c.786C>T p.D262= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs910443434, COSV58272225; called by muse, mutect2, varscan2
- AOC1 | c.1143C>T p.V381= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV62868997; called by muse, mutect2, varscan2
- ASXL3 | c.6646C>A p.R2216= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV52461639, COSV52467723; called by muse, mutect2, varscan2
- BSN | c.2709G>T p.T903= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV56519422; called by muse, mutect2, varscan2
- BUD31 | c.108G>A p.P36= | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as rs761565625, COSV52864026; called by muse, mutect2
- C5orf22 | c.504A>G p.Q168= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV57598643; called by muse, mutect2, varscan2
- CABLES2 | c.1044C>T p.F348= | Silent (SNP) | VAF 39/195 reads (20%) | catalogued as COSV54157017; called by muse, varscan2
- CHD8 | c.2679G>T p.L893= (on ENST00000646647 / NM_001170629.2; = p.L614= on NM_020920.4) | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs1464666262, COSV67870781; called by muse, varscan2
- CHRM4 | c.52C>T p.L18= | Silent (SNP) | VAF 60/179 reads (34%) | catalogued as COSV63126593; called by muse, mutect2, varscan2
- CIDEA | c.651G>T p.T217= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV57598754; called by muse, mutect2, varscan2
- CLCN1 | c.1650G>T p.T550= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- CMPK2 | c.771C>T p.I257= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as rs371005529; called by muse, mutect2, varscan2
- CP | c.2925C>T p.H975= | Silent (SNP) | VAF 26/261 reads (10%) | catalogued as rs377478882; called by muse, mutect2, varscan2
- CRYM | c.570G>A p.S190= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs754359609, COSV54831585, COSV54831801; called by muse, mutect2, varscan2
- CTNND1 | c.1521T>G p.G507= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV62383842; called by muse, mutect2, varscan2
- DISP2 | c.2178C>T p.R726= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV51123833; called by muse, mutect2
- DLC1 | c.2532C>T p.H844= (on ENST00000276297 / NM_001348081.2; = p.H407= on NM_006094.5) | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as rs371738249, COSV52307308; called by muse, mutect2, varscan2
- EIF3H | c.492A>G p.L164= | Silent (SNP) | VAF 49/137 reads (36%) | catalogued as rs1309365499, COSV52667332; called by muse, mutect2, varscan2
- EXO1 | c.633G>C p.T211= | Silent (SNP) | VAF 31/305 reads (10%) | catalogued as rs565914499, COSV62217820; called by muse, mutect2, varscan2
- FAM135B | c.3972C>A p.A1324= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV52728891; called by muse, mutect2, varscan2
- FAM13C | c.1128G>C p.P376= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV53249438; called by muse, mutect2, varscan2
- FAP | c.789G>T p.R263= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV51862461; called by muse, mutect2, varscan2
- FAR2 | c.1062G>A p.A354= | Silent (SNP) | VAF 53/356 reads (15%) | catalogued as rs142086556; called by muse, mutect2, varscan2
- FAT4 | c.6489T>C p.I2163= | Silent (SNP) | VAF 53/160 reads (33%) | catalogued as COSV58688494; called by muse, mutect2, varscan2
- FIGLA | c.555T>C p.A185= | Silent (SNP) | VAF 150/494 reads (30%) | catalogued as COSV60089231; called by muse, mutect2, varscan2
- FKBP6 | c.66C>T p.Y22= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as rs1322846011, COSV52720500; called by muse, mutect2
- FLRT2 | c.963C>T p.V321= | Silent (SNP) | VAF 62/296 reads (21%) | catalogued as COSV58142637; called by muse, varscan2
- FOXD4L5 | c.60C>T p.S20= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as COSV101073060; called by muse, mutect2, varscan2
- GALNT16 | c.222G>T p.L74= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV61886270; called by muse, mutect2, varscan2
- GLB1L3 | c.1215C>A p.P405= | Silent (SNP) | VAF 85/358 reads (24%) | catalogued as rs1332319856, COSV68392861; called by muse, mutect2, varscan2
- GPATCH3 | c.51G>A p.V17= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as COSV64652176; called by muse, mutect2, varscan2
- GRM5 | c.48C>A p.V16= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV59607549; called by muse, mutect2, varscan2
- GUCY2F | c.3105G>T p.L1035= | Silent (SNP) | VAF 124/204 reads (61%) | catalogued as COSV54303160; called by muse, mutect2, varscan2
- HBE1 | c.342T>C p.I114= | Silent (SNP) | VAF 53/259 reads (20%) | catalogued as COSV53080218; called by muse, mutect2, varscan2
- HIRIP3 | c.1422A>C p.L474= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV54230244; called by muse, mutect2, varscan2
- HUNK | c.1455G>T p.R485= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV54229041; called by muse, mutect2, varscan2
- IGHV1-2 | c.33G>A p.V11= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- IL20RA | c.1092G>A p.S364= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs202196623, COSV57357663; called by muse, mutect2, varscan2
- ILF3 | c.246G>A p.T82= | Silent (SNP) | VAF 89/296 reads (30%) | catalogued as rs769019863, COSV51558463; called by muse, mutect2, varscan2
- KCNA1 | c.813C>A p.T271= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV101230159; called by muse, mutect2, varscan2
- KCNA4 | c.1218C>T p.I406= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV60252782; called by muse, mutect2, varscan2
- KIF23 | c.96G>A p.V32= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs1257821692, COSV52980261; called by muse, mutect2, varscan2
- KIF3B | c.804C>A p.I268= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV65227829; called by muse, mutect2, varscan2
- KIR3DL3 | c.6G>T p.S2= | Silent (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- LAMA2 | c.7827T>A p.I2609= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV70348743; called by muse, mutect2, varscan2
- LGSN | c.213T>C p.S71= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV65727383; called by muse, mutect2, varscan2
- LINGO2 | c.1452C>A p.I484= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs150860330, COSV58058320; called by muse, mutect2, varscan2
- LRRC15 | c.1062G>A p.Q354= | Silent (SNP) | VAF 82/102 reads (80%) | catalogued as COSV61650272; called by muse, mutect2, varscan2
- LRRC73 | c.831G>A p.R277= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs777151511, COSV52501268; called by muse, mutect2, varscan2
- LRRTM1 | c.1365C>A p.A455= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV54442327; called by muse, mutect2, varscan2
- MTUS2 | c.249C>A p.G83= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV70917098; called by muse, mutect2, varscan2
- NFATC1 | c.1942C>A p.R648= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV104388975, COSV99500941; called by muse, mutect2, varscan2
- NINJ2 | c.93G>A p.K31= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs778128290, COSV56753031; called by muse, mutect2, varscan2
- NLGN1 | c.2406A>G p.G802= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV64335341; called by muse, mutect2, varscan2
- NSD3 | c.960G>T p.A320= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs748971560, COSV57619357; called by muse, mutect2, varscan2
- OR4A5 | c.855G>C p.T285= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV60522804, COSV60522908; called by muse, mutect2, varscan2
- OR4K1 | c.636G>C p.L212= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV53460460; called by muse, mutect2, varscan2
- OR4P4 | c.219C>A p.S73= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as COSV58922141; called by muse, mutect2, varscan2
- PCDH17 | c.2100C>T p.H700= | Silent (SNP) | VAF 74/122 reads (61%) | catalogued as COSV64974751; called by muse, mutect2, varscan2
- PCDHB5 | c.1560C>T p.Y520= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV50653791; called by muse, mutect2, varscan2
- PCNX1 | c.6249G>A p.Q2083= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV53095530; called by muse, mutect2, varscan2
- PCP4L1 | c.90G>A p.A30= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as rs752580065, COSV73440683; called by muse, mutect2, varscan2
- PIGS | c.1266G>A p.E422= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV52024735; called by muse, mutect2, varscan2
- PLXNA2 | c.3480G>A p.S1160= | Silent (SNP) | VAF 33/219 reads (15%) | catalogued as rs753774411, COSV65441291; called by muse, mutect2, varscan2
- POGLUT2 | c.1320A>G p.Q440= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as COSV65683195; called by muse, mutect2, varscan2
- POLK | c.2394G>T p.V798= | Silent (SNP) | VAF 72/145 reads (50%) | catalogued as COSV54035749; called by muse, mutect2, varscan2
- PPFIA3 | c.1071C>T p.A357= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV61952108; called by muse, mutect2, varscan2
- PPM1L | c.234C>G p.L78= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs749607446, COSV72263218; called by muse, mutect2, varscan2
- PRICKLE2 | c.1299C>T p.D433= (on ENST00000295902; = p.D377= on NM_198859.4) | Silent (SNP) | VAF 88/158 reads (56%) | catalogued as COSV55766840; called by muse, mutect2, varscan2
- PRKCZ | c.603C>T p.D201= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs757956708, COSV66067947; called by muse, mutect2, varscan2
- PTPRN2 | c.805C>T p.L269= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, varscan2
- RADIL | c.1098C>A p.A366= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- RBBP8NL | c.1848G>A p.R616= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs1053471318, COSV53349369; called by muse, mutect2, varscan2
- RNF182 | c.18T>G p.P6= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as COSV70369350; called by muse, mutect2, varscan2
- RNF20 | c.87G>A p.G29= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV66355702; called by muse, mutect2, varscan2
- RXRG | c.1164T>C p.S388= | Silent (SNP) | VAF 88/140 reads (63%) | catalogued as rs766520723, COSV63232248; called by muse, mutect2, varscan2
- RYR3 | c.3282G>A p.V1094= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV66792259; called by muse, mutect2, varscan2
- SCNN1B | c.1053T>C p.L351= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as COSV56305170; called by muse, mutect2, varscan2
- SDC1 | c.216G>A p.T72= | Silent (SNP) | VAF 44/273 reads (16%) | catalogued as rs763131464, COSV54340062; called by muse, mutect2, varscan2
- SEC23IP | c.390G>A p.S130= | Silent (SNP) | VAF 41/235 reads (17%) | catalogued as rs201913734, COSV64831063; called by muse, mutect2, varscan2
- SLC2A14 | c.213G>A p.T71= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs1253638586, COSV61586833, COSV61588020; called by muse, mutect2, varscan2
- SLCO1B3 | c.891T>C p.H297= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV53938710; called by mutect2, varscan2
- SMR3B | c.27C>A p.G9= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV100513335; called by muse, mutect2, varscan2
- SPACA1 | c.555A>C p.T185= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV52760114; called by muse, mutect2, varscan2
- SPATA2 | c.1332G>A p.P444= | Silent (SNP) | VAF 32/179 reads (18%) | catalogued as rs376954971; called by muse, mutect2, varscan2
- SPATA31E1 | c.3840C>A p.G1280= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV57792179; called by muse, mutect2, varscan2
- ST7 | c.219A>T p.I73= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV55385964; called by muse, mutect2, varscan2
- SURF4 | c.171C>T p.T57= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV64338933; called by muse, mutect2, varscan2
- TG | c.4323G>C p.S1441= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV55078811, COSV55082998, COSV99601051; called by muse, mutect2, varscan2
- TJP3 | c.975C>A p.T325= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53665843, COSV99515855; called by muse, mutect2, varscan2
- TMC2 | c.795C>A p.V265= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV62653486; called by muse, mutect2, varscan2
- TMEM151A | c.822C>A p.A274= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs772573280, COSV59173211, COSV59173934; called by muse, mutect2, varscan2
- TMEM263 | c.147T>A p.A49= | Silent (SNP) | VAF 49/208 reads (24%) | catalogued as COSV55014167; called by muse, mutect2, varscan2
- TNK2 | c.1419C>T p.R473= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV57370248; called by muse, mutect2, varscan2
- TRERF1 | c.1908G>T p.P636= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as COSV61672617; called by muse, mutect2, varscan2
- TRGV4 | c.330C>G p.V110= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.51567G>A p.K17189= (on ENST00000591111; = p.K9765= on NM_003319.4) | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as COSV60104183; called by muse, mutect2, varscan2
- TVP23B | c.132A>T p.R44= | Silent (SNP) | VAF 145/285 reads (51%) | catalogued as COSV57060045; called by muse, mutect2, varscan2
- U2AF2 | c.1122G>C p.P374= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs748433023, COSV58274166; called by muse, mutect2, varscan2
- UGT2A1 | c.540A>G p.E180= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs746258949, COSV54142201; called by muse, mutect2
- VIT | c.426G>A p.K142= | Silent (SNP) | VAF 95/298 reads (32%) | catalogued as COSV64896857; called by muse, mutect2, varscan2
- WAC | c.1404G>A p.L468= | Silent (SNP) | VAF 87/213 reads (41%) | catalogued as rs781071847, COSV61567749; called by muse, mutect2, varscan2
- XIRP2 | c.5814C>A p.S1938= (on ENST00000628543; = p.S2113= on NM_152381.6) | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54704346; called by muse, mutect2, varscan2
- XRN1 | c.4428A>G p.L1476= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as COSV53812668; called by muse, mutect2, varscan2
- ZEB1 | c.735T>C p.C245= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV58045580; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169765032 A>T | 3'Flank (SNP) | VAF 14/106 reads (13%) | catalogued as rs1336050074; ClinVar: uncertain significance; called by muse, mutect2
- ANK1 | c.5619+322G>T | Intron (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99224406; called by muse, mutect2, varscan2
- DPH6 | c.312+16054A>C | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99853384; called by muse, mutect2, varscan2
- MYL3 | chr3:46830439 C>T | 3'Flank (SNP) | VAF 8/19 reads (42%) | catalogued as rs1305662574, COSV101451278, COSV70133789; called by muse, mutect2, varscan2
- NOP58 | c.122+1272G>A | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99970483; called by muse, mutect2, varscan2
- SNORD116-15 | n.44A>T | RNA (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- SNORD116-22 | n.51G>T | RNA (SNP) | VAF 29/180 reads (16%) | called by muse, mutect2, varscan2
- STAG3L4 | n.590G>T | RNA (SNP) | VAF 185/354 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.10361-5171T>A | Intron (SNP) | VAF 36/221 reads (16%) | catalogued as COSV60104268; called by muse, mutect2, varscan2
- WDR43 | c.607-395G>T | Intron (SNP) | VAF 46/192 reads (24%) | catalogued as COSV99942929; called by muse, mutect2, varscan2
- XIRP2 | c.*446C>A | 3'UTR (SNP) | VAF 57/131 reads (44%) | catalogued as COSV99739902; called by muse, mutect2, varscan2
- XIST | n.11321G>C | RNA (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
